Somatic mutation profile of tumor specimen TCGA-19-1387-01A (aliquot TCGA-19-1387-01A-01W-0643-08) from TCGA case TCGA-19-1387, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 81.8 years (29,892 days).
Specimen TCGA-19-1387-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ee853e4-e5f9-4116-8b9d-5633e21dce97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-1387-10C (Blood Derived Normal), aliquot TCGA-19-1387-10C-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db364504-f4c0-43d5-bd7f-059bdfb9fe95

The open-access MAF lists 81 somatic variants for this specimen: 62 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 18, Nonsense Mutation 4, Frame Shift Del 3, In Frame Del 1, Splice Region 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDB2 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 116/193 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs121434640, CM960485, COSV99921391; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.2983G>T p.A995S | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV99709928; called by muse, mutect2, varscan2
- ADCY3 | c.2810C>T p.T937I | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774480624, COSV99567489; called by muse, mutect2, varscan2
- ALDH3A2 | c.1316G>A p.R439K | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99449481; called by muse, mutect2, varscan2
- ARHGAP11A | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 58/97 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100853134; called by muse, mutect2, varscan2
- CCDC40 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV53898100; called by muse, mutect2
- CFAP47 | c.959A>G p.D320G | Missense Mutation (SNP) | VAF 57/67 reads (85%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.923); catalogued as COSV99934073; called by muse, mutect2, varscan2
- CSMD2 | c.2159G>A p.G720D | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99584413; called by muse, mutect2
- CUL7 | c.3076G>T p.D1026Y | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99537562; called by muse, mutect2
- CYP4B1 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs200083913, COSV54723008; called by muse, mutect2, varscan2
- ECT2L | c.1080T>G p.I360M | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100871715; called by muse, mutect2, varscan2
- EGFLAM | c.1874C>T p.P625L | Missense Mutation (SNP) | VAF 17/292 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100379575; called by muse, mutect2
- GABARAPL2 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.801); catalogued as COSV99231085; called by muse, mutect2, varscan2
- H2AC11 | c.152A>T p.Y51F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60362642; called by mutect2, varscan2
- HSPG2 | c.7030C>T p.R2344C | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs752260236, COSV65973744; called by muse, mutect2
- HYOU1 | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs781887339, COSV101345527, COSV68215285; called by muse, mutect2, varscan2
- IGF1R | c.2075G>T p.C692F | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99148038; called by muse, mutect2, varscan2
- IGF2BP3 | c.107A>G p.K36R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.177); catalogued as COSV99324836; called by muse, mutect2, varscan2
- IMP4 | c.282T>G p.S94R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99383568; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1217C>T p.S406F (on ENST00000485419 / NM_001197113.1; = p.S330F on NM_014575.3) | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100539230; called by muse, mutect2, varscan2
- JMJD6 | c.868A>G p.S290G | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100372831; called by muse, mutect2
- KCTD16 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.021); catalogued as rs373329363, COSV101568678; called by muse, mutect2, varscan2
- KIF4B | c.926T>G p.M309R | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101469143; called by muse, mutect2, varscan2
- KLKB1 | c.489G>A p.R163= | Splice Region (SNP) | VAF 6/88 reads (7%) | catalogued as COSV99249497; called by muse, mutect2
- KRTAP4-1 | c.436T>G p.C146G (on ENST00000398472; = p.C127G on NM_033060.3) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); catalogued as COSV100893376, COSV66648087; called by muse, mutect2
- MED12 | c.755A>G p.H252R | Missense Mutation (SNP) | VAF 182/230 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV100375375; called by muse, mutect2, varscan2
- NACA2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs752237901, COSV101478527; called by muse, mutect2, varscan2
- NAV3 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1201502825, COSV99885829; called by muse, mutect2, varscan2
- NEO1 | c.4034G>A p.G1345D | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs777996982, COSV99981080; called by muse, mutect2, varscan2
- NPRL2 | c.883C>G p.R295G | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as CM160817, COSV51603126, COSV99204428; called by muse, mutect2, varscan2
- OR11H1 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 40/690 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs369991794, COSV99421499; called by muse, mutect2
- OR2M5 | c.688T>A p.S230T | Missense Mutation (SNP) | VAF 113/756 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.26); catalogued as COSV100822703; called by muse, mutect2, varscan2
- OSBPL3 | c.267+2T>A p.X89_splice | Splice Site (SNP) | VAF 39/301 reads (13%) | catalogued as COSV100513539; called by muse, mutect2, varscan2
- P2RX7 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99947367; called by muse, mutect2, varscan2
- PCDHA13 | c.1440G>C p.Q480H | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs782444555, COSV99164858; called by muse, mutect2, varscan2
- PIK3CG | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs554272230, COSV63247299; called by muse, mutect2, varscan2
- POU6F1 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100374699; called by muse, mutect2, varscan2
- PRKAG1 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 46/349 reads (13%) | catalogued as COSV60292718; called by muse, mutect2, varscan2
- PTEN | c.564T>G p.Y188* | Nonsense Mutation (SNP) | VAF 159/219 reads (73%) | catalogued as COSV64301503, COSV64310336; called by muse, mutect2, varscan2
- PTPRS | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99508620; called by muse, varscan2
- RASEF | c.871T>G p.L291V | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as COSV100906743; called by muse, mutect2, varscan2
- RNF20 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV101206492; called by muse, mutect2, varscan2
- RPGRIP1L | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.614); catalogued as COSV100045643; called by muse, mutect2, varscan2
- SENP7 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 132/378 reads (35%) | catalogued as rs754445227, COSV100052089; called by muse, mutect2, varscan2
- SGSM2 | c.2742G>T p.W914C (on ENST00000426855 / NM_001098509.2; = p.W959C on NM_014853.3) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99279611; called by muse, mutect2, varscan2
- SLC23A2 | c.1130C>T p.A377V | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as rs924661982, COSV100594691; called by muse, mutect2, varscan2
- SLC2A14 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 97/245 reads (40%) | SIFT tolerated (0.86); PolyPhen benign (0.019); catalogued as rs771821320, COSV61585468; called by muse, mutect2, varscan2
- SLCO6A1 | c.758T>C p.F253S | Missense Mutation (SNP) | VAF 236/414 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65806255; called by muse, mutect2, varscan2
- SRGAP3 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV100840619, COSV64536859; called by muse, mutect2, varscan2
- SYTL4 | c.1328A>G p.Q443R | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs748202932, COSV52165491, COSV99342577; called by muse, mutect2, varscan2
- TERT | c.3101G>A p.R1034H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs62331332, COSV99715636; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TIMM44 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as COSV99563786; called by muse, mutect2
- TNK2 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100360837; called by muse, mutect2, varscan2
- TNN | c.1447G>C p.D483H | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV53433320, COSV99510797; called by muse, mutect2, varscan2
- ZHX3 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.422); catalogued as rs747830614, COSV58390271; called by muse, mutect2, varscan2
- ZNF443 | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 92/205 reads (45%) | catalogued as rs201995811, COSV100041837; called by muse, mutect2, varscan2
- C1orf43 | c.428del p.S143Ifs*41 (on ENST00000368521 / NM_001297718.2; = p.S109Ifs*41 on NM_015449.4) | Frame Shift Del (DEL) | VAF 18/136 reads (13%) | called by mutect2, varscan2
- IDE | c.2440A>T p.I814F | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by mutect2, varscan2
- NEK11 | c.147_149del p.K50del | In Frame Del (DEL) | VAF 14/160 reads (9%) | called by mutect2, pindel
- NINL | c.859del p.Q287Rfs*68 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- PNPO | c.404del p.P135Hfs*7 (on ENST00000225573; = p.P135Hfs*12 on NM_018129.4) | Frame Shift Del (DEL) | VAF 63/149 reads (42%) | called by mutect2, pindel, varscan2
- BMP5 | c.138C>T p.H46= | Silent (SNP) | VAF 90/206 reads (44%) | catalogued as rs773535817, COSV100895669; called by muse, mutect2
- CDHR2 | c.324G>A p.R108= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV56138755; called by muse, mutect2, varscan2
- CERKL | c.633C>T p.H211= | Silent (SNP) | VAF 58/143 reads (41%) | catalogued as rs201656622; called by muse, mutect2, varscan2
- CLUAP1 | c.933C>T p.N311= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs750353977, COSV58895516; called by muse, mutect2, varscan2
- CPS1 | c.2298G>T p.L766= | Silent (SNP) | VAF 14/356 reads (4%) | catalogued as COSV51817836, COSV99241480; called by muse, mutect2
- EFCAB3 | c.693C>T p.S231= | Silent (SNP) | VAF 70/261 reads (27%) | catalogued as rs767957301, COSV59504501; called by muse, mutect2, varscan2
- ELOA2 | c.363C>T p.S121= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV99795680; called by muse, mutect2, varscan2
- HEPACAM | c.729C>T p.I243= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as COSV100005378; called by muse, mutect2
- HPDL | c.984G>A p.K328= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as COSV100587861; called by muse, mutect2, varscan2
- KRTAP19-2 | c.117C>T p.C39= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs1443692666, COSV100477405; called by muse, mutect2
- MCM5 | c.900G>A p.Q300= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV99331391; called by muse, mutect2, varscan2
- NCOA6 | c.5637A>C p.P1879= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV100749872; called by muse, mutect2, varscan2
- OR4P4 | c.825C>T p.I275= | Silent (SNP) | VAF 59/149 reads (40%) | catalogued as COSV100111495; called by muse, mutect2, varscan2
- POTEH | c.369C>T p.H123= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs375881965, COSV100625116; called by muse, varscan2
- PPIP5K2 | c.3423G>A p.K1141= (on ENST00000358359 / NM_001276277.3; = p.K1120= on NM_015216.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 45/130 reads (35%) | catalogued as rs115289997, COSV100383331; called by muse, mutect2, varscan2
- TACC2 | c.5403C>T p.D1801= | Silent (SNP) | VAF 33/40 reads (83%) | catalogued as rs773442499, COSV100551240; called by muse, mutect2, varscan2
- ZFAT | c.2373G>A p.Q791= | Silent (SNP) | VAF 105/369 reads (28%) | catalogued as rs1160650000, COSV100914095; called by muse, mutect2, varscan2
- ZNF676 | c.1089T>C p.H363= (on ENST00000650058; = p.H331= on NM_001001411.3) | Silent (SNP) | VAF 59/267 reads (22%) | catalogued as COSV101236070, COSV68095098; called by muse, mutect2, varscan2
- SNORD115-20 | n.77A>T | RNA (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
